Somatic mutation profile of tumor specimen TARGET-10-PARMRF-09A (aliquot TARGET-10-PARMRF-09A-01D) from TARGET case TARGET-10-PARMRF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,186 days).
Specimen TARGET-10-PARMRF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8e5414d-9aa0-4702-a6f9-fe3ac80f4475.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMRF-14A (Bone Marrow Normal), aliquot TARGET-10-PARMRF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/452a2776-ad17-4e56-837c-28306caceaa6

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Ins 4, 3'UTR 2, In Frame Del 1, Intron 1, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1321C>G p.R441G (on ENST00000281708 / NM_001349798.2; = p.R361G on NM_018315.5) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55897212, COSV55936558; called by muse, mutect2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 42/132 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, varscan2
- CTCF | c.1071_1072insGGGCCC p.D357_Y358insGP | In Frame Ins (INS) | VAF 9/71 reads (13%) | catalogued as COSV50538963; called by mutect2, pindel, varscan2
- DACT1 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1369994515, COSV60021323; called by muse, mutect2, varscan2
- DNAJB4 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV66132220; called by muse, mutect2, varscan2
- ECHDC2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs368580572; called by muse, mutect2, varscan2
- IQSEC3 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.318); catalogued as COSV58292377; called by muse, mutect2, varscan2
- KCNJ4 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1175555242, COSV100341218, COSV57859220; called by muse, mutect2, varscan2
- LILRA2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs768414857, COSV52198598; called by muse, mutect2, varscan2
- LNX1 | c.834T>A p.N278K (on ENST00000263925 / NM_001126328.3; = p.N182K on NM_032622.2) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as rs1168128775, COSV55792973; called by muse, mutect2, varscan2
- MAB21L4 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs748298781, COSV56745103; called by muse, mutect2
- PTEN | c.696dup p.R233Tfs*10 | Frame Shift Ins (INS) | VAF 16/102 reads (16%) | catalogued as CI147229, COSV64305740; called by pindel, varscan2
- SLCO5A1 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs746132395, COSV52670285; called by muse, mutect2, varscan2
- TGFBI | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs1294925461, COSV59354986; called by muse, mutect2, varscan2
- USP7 | c.639_640insCGCCCCCCCC p.V214Rfs*41 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as COSV100784154; called by mutect2, varscan2
- ZNF335 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs1221132687, COSV59820098, COSV59820884; called by muse, mutect2, varscan2
- NOTCH1 | c.7314_7315insGTCTTGAG p.S2439Vfs*41 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- PIK3R1 | c.1691_1693del p.N564del (on ENST00000521381 / NM_181523.3; = p.N294del on NM_181504.4) | In Frame Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- PTEN | c.703_704insCCCCCCGG p.E235Afs*24 | Frame Shift Ins (INS) | VAF 20/102 reads (20%) | called by pindel, varscan2
- KDM4E | c.597C>T p.N199= | Silent (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- KAT6B | c.3021+93G>A | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- LMBR1 | c.*3C>T | 3'UTR (SNP) | VAF 10/59 reads (17%) | catalogued as rs747448254; called by muse, mutect2, varscan2
- RASSF2 | c.*38G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | catalogued as rs779239522, COSV101040653; called by muse, mutect2, varscan2
